Gene-level copy-number profile of tumor specimen TCGA-EE-A29A-06A from TCGA case TCGA-EE-A29A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.3 years (26,779 days).
Specimen TCGA-EE-A29A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.521fa068-5f32-4952-80c5-121f00a4d0e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/502cca00-113e-4292-828b-b02e643d7e27

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 1; copy number 2: 3,923; copy number 3: 2,055; copy number 4: 40,495; copy number 5: 4,760; copy number 6: 5,121; copy number 8: 104; copy number 9: 3,311.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29A-06A-12D-A194-01): tumor purity 0.81, ploidy 4.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–27,297,150, 49 genes: CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,311 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–125,482,966, 2,234 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr7:125,917,871–159,233,377, 778 genes, copy number 9 (broad region; genes not listed).
- chr9:14,475–18,910,950, 229 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:106,061,354–106,064,825, 1 gene, copy number 9: AL732323.1.
- chr9:113,373,419–115,402,644, 37 genes, copy number 9 (within-gene range 3–9): HDHD3, ALAD, POLE3, C9orf43, RGS3, AL162727.2, AL162727.3, AL162727.1, AL157702.2, AL157702.1, AL162393.1, ZNF618, AMBP, KIF12, COL27A1, MIR455, ORM1, ORM2, AKNA, AL138895.1, WHRN, AL138895.2, AL160275.2, ATP6V1G1, TMEM268, Y_RNA, TEX53, TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1.
- chr9:116,425,225–117,415,070, 1 gene, copy number 9 (within-gene range 4–9): ASTN2.
- chr9:116,687,305–118,764,345, 18 genes, copy number 9: TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6.
- chr9:122,403,407–122,639,685, 1 gene, copy number 9 (within-gene range 4–9): AL359636.2.
- chr9:122,510,802–122,724,925, 12 genes, copy number 9: OR1J2, OR1J4, OR1N1, OR1N2, OR1L8, OR1H1P, OR1Q1, OR1B1, OR1L1, OR1L3, TLK1P1, OR1L4.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
